Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MR, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MR-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:

Male

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

Male XX

108-0-3

Melanoma, NOS 8720/3

Site: lymph node, axillary 277.3

CLINICAL DETAILS

Met. melanoma right axilla. 1. Right axilla dissection suture apex. 2. Excision of BCC right chest.

hw

8/24/11

MACROSCOPIC DESCRIPTION

(Dr

Two specimens were received.

1. "RIGHT AXILLA SUTURE AT APEX". The specimen consists of an orientated irregularly shaped piece of fibrofatty tissue, measuring 235 x 110 x 60mm in maximum extent and weighing 410g. There is a stitch at one end designated as the apex. Also included in and attached to the rest of the specimen are two pieces of skeletal muscle measuring 65 x 60 x 25mm and 25 x 25 x 15mm in maximum extent. There is also an ellipse of unremarkable skin, measuring 55 x 10mm, attached to one side of the specimen. The largest lymph node measures 45 x 35 x 30mm in maximum extent. Largest lymph node lies 25mm below the skin surface. Lymph nodes embedded from apex.

- A. Apical lymph node
- B. Four lymph nodes
- C. One lymph node bisected
- D. Three lymph nodes
- E. Four lymph nodes
- F. One lymph node bisected
- G. One lymph node
- H - L. Full face of the largest lymph node with tumour
- M. Representative section of the muscle.
- N. Representative section of the skin.

2. "MELANOMA CHEST WALL SUTURE SUPERIOR". The specimen consists of an orientated ellipse of skin measuring 45 x 20 to a depth of 5mm with a suture at superior border designated as 12 o'clock. On the skin surface, there are two ulcerated areas measuring 5 x 2mm and 3 x 2mm in maximum extent which are well clear of the resection margins. 12 o'clock half is inked blue and 6 o'clock half is inked black. The specimen is transversely sectioned from 3 o'clock to 9 o'clock.

- A. 3 o'clock margin
- B. 9 o'clock margin
- C - E. Transverse sections from 3 o'clock to 9 o'clock. All lesion embedded.

MICROSCOPIC REPORT

1. One (1) of the sixteen lymph nodes identified contains metastatic spindle cell malignant melanoma. No definite extranodal spread is identified. The tumour extends to 0.2mm from the apparent resection margin focally. The apical lymph node is not involved by tumour.

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

2. Sections of skin show a sclerosing (morphoeic) basal cell carcinoma which infiltrates into the lower dermis. The lesion appears clear of the peripheral/cutaneous resection margins by 4mm and of the deep resection margin by 4mm.

SPECIAL INVESTIGATIONS

Immunohistochemistry -

S100: positive

HMB45: negative

Melan A: negative

Tyrosinase: negative

SUMMARY

1. Right axillary lymph nodes: Metastatic malignant melanoma - See above microscopic report.
/

2. Chest wall: Basal cell carcinoma.

REPORTED BY:

Source: NCI Genomic Data Commons file 94faa333-4552-4817-af39-8bfcad3eed20 (TCGA-EE-A2MR.5835D1B9-D1BB-4582-A9D0-5A441DDA28B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).